Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5732, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5732-01A (Primary Tumor).

*** Diagnosis(es): ***

Total gastrectomy specimen including an extensive, extensively ulcerated, moderately differentiated gastric adenocarcinoma (intestinal type) located in the cardia/corpus area with wide infiltration of the perimuscular soft tissue and with 17 regional lymph node metastases. Tumour-free oesophageal resection margin lined with unremarkable squamous epithelium and tumour-free duodenal resection margin.

Tumour stage: pT2b pN3 (17/31) pMX; [REDACTED]

Source: NCI Genomic Data Commons file 45eab1e2-20f0-4850-8865-b36fe5101326 (TCGA-CG-5732.DD80E769-50E7-424D-978A-672EA737780C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).